Somatic mutation profile of tumor specimen TCGA-AX-A0IW-01A (aliquot TCGA-AX-A0IW-01A-11W-A062-09) from TCGA case TCGA-AX-A0IW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 67.0 years (24,488 days).
Specimen TCGA-AX-A0IW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 084be19d-3648-4c30-af14-1bb973569d6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A0IW-10A (Blood Derived Normal), aliquot TCGA-AX-A0IW-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9074490-11c2-4889-9d1f-c0859fd92f54

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 37, Silent 13, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCSL | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66581090; called by muse, mutect2, varscan2
- ADAM23 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 117/137 reads (85%) | catalogued as rs1195575532, COSV52207862; called by muse, mutect2, varscan2
- AFF3 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57852643; called by muse, mutect2, varscan2
- AK1 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV56344840, COSV56345062; called by muse, mutect2, varscan2
- C2CD5 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 114/295 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV61724320; called by muse, mutect2, varscan2
- DENND4B | c.1024G>C p.V342L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV63408873, COSV63409507; called by muse, mutect2, varscan2
- DNAH7 | c.11951G>A p.R3984K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.779); catalogued as COSV56762734; called by muse, mutect2, varscan2
- DYRK4 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763765045, COSV50538264; called by muse, mutect2, varscan2
- EDA | c.396+1G>C p.X132_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | catalogued as COSV58876916; called by muse, mutect2
- EWSR1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs764280754, COSV58423285; called by mutect2, varscan2
- FANCB | c.2427C>G p.I809M | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60759710; called by muse, mutect2
- FAT1 | c.13321G>T p.D4441Y | Missense Mutation (SNP) | VAF 31/331 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV71673602, COSV71674760; called by muse, mutect2, varscan2
- FGA | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs560911144, COSV57395542; called by muse, mutect2, varscan2
- GLI1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs972690369, COSV57360984, COSV57368649; called by muse, mutect2
- H1-4 | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as COSV56800905; called by muse, mutect2, varscan2
- HERC2 | c.12507G>A p.W4169* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV55321507; called by muse, mutect2, varscan2
- HMGCL | c.843_850del p.V282Afs*31 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | catalogued as COSV52525723; called by mutect2, pindel, varscan2
- IMP4 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs777096793, COSV52091651; called by muse, mutect2, varscan2
- KAT14 | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as COSV66607546; called by muse, mutect2
- KCTD1 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1014368737, COSV58685765; called by muse, mutect2, varscan2
- MGAT4A | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1435139019, COSV53846898; called by muse, mutect2, varscan2
- MORC4 | c.2530G>C p.A844P | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV55241675; called by muse, mutect2
- MTRF1 | c.1204T>C p.Y402H | Missense Mutation (SNP) | VAF 169/590 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.771); catalogued as COSV65263254; called by muse, mutect2, varscan2
- MUC16 | c.23715G>T p.M7905I | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV67440836, COSV67462660; called by muse, mutect2, varscan2
- PPP1R3A | c.2288A>G p.D763G | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52881496; called by muse, mutect2, varscan2
- PRKACA | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747585702, COSV58067766; called by muse, mutect2, varscan2
- PSG1 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 327/869 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV54948813; called by muse, mutect2, varscan2
- RAPH1 | c.3293C>T p.S1098F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV55583601; called by muse, mutect2, varscan2
- RBM15 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63923046; called by muse, mutect2, varscan2
- RORB | c.926G>C p.G309A (on ENST00000396204 / NM_001365023.1; = p.G298A on NM_006914.4) | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65335485; called by muse, mutect2, varscan2
- RSPH3 | c.662G>A p.R221K (on ENST00000252655; = p.R79K on NM_031924.8) | Missense Mutation (SNP) | VAF 43/422 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as rs1258187275, COSV51922468; called by muse, mutect2
- SF3A1 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53168600; called by muse, mutect2, varscan2
- SHB | c.1008C>A p.Y336* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV66628991; called by muse, mutect2, varscan2
- SNTG1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs764804995, COSV52440797; called by muse, mutect2, varscan2
- SUSD6 | c.182G>C p.R61T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV61365242; called by muse, mutect2, varscan2
- SYCP2 | c.535A>G p.M179V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs770812931, COSV62768058; called by muse, mutect2, varscan2
- TMEM31 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV60327580; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 39/65 reads (60%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TRIO | c.3811T>G p.S1271A | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.086); catalogued as COSV60082848, COSV60093388; called by muse, mutect2, varscan2
- TTC21B | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 72/353 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV54630089; called by muse, mutect2, varscan2
- USH2A | c.12919T>C p.Y4307H | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs770441733, COSV56363016; called by muse, mutect2, varscan2
- ZNF248 | c.690T>A p.F230L | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61997619; called by muse, mutect2, varscan2
- ZNF354C | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866051885, COSV59608122; called by muse, mutect2
- ASXL3 | c.5700_5707dup p.S1903Cfs*85 | Frame Shift Ins (INS) | VAF 22/168 reads (13%) | called by mutect2, varscan2
- ATP13A5 | c.2736C>T p.Y912= | Silent (SNP) | VAF 144/295 reads (49%) | catalogued as rs374767252, COSV60868750; called by muse, mutect2, varscan2
- CRB1 | c.498A>T p.G166= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as CD061397, COSV66340036; called by muse, mutect2, varscan2
- CTAGE6 | c.762C>T p.H254= | Silent (SNP) | VAF 72/249 reads (29%) | catalogued as rs1229403497, COSV69917186; called by muse, mutect2, varscan2
- MAN2A1 | c.984G>A p.L328= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as COSV54851115; called by muse, mutect2, varscan2
- NAA38 | c.72C>T p.S24= (on ENST00000575771 / NM_001320925.2; = p.P11L on NM_032356.5) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV54681086; called by muse, mutect2, varscan2
- NAF1 | c.576G>A p.L192= | Silent (SNP) | VAF 84/257 reads (33%) | catalogued as COSV56804229; called by muse, mutect2, varscan2
- NPHS1 | c.513C>T p.I171= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV62287605; called by muse, mutect2, varscan2
- PLA2G4A | c.2181T>C p.S727= | Silent (SNP) | VAF 31/249 reads (12%) | catalogued as rs761783969, COSV66553631; called by muse, mutect2, varscan2
- RAB30 | c.225C>T p.T75= | Silent (SNP) | VAF 12/278 reads (4%) | catalogued as COSV52626539; called by muse, mutect2
- SLC26A8 | c.18G>A p.R6= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV62885613; called by muse, mutect2, varscan2
- SLC51A | c.597G>A p.L199= | Silent (SNP) | VAF 41/228 reads (18%) | catalogued as COSV56351546; called by muse, varscan2
- SLC5A8 | c.840C>G p.L280= | Silent (SNP) | VAF 80/158 reads (51%) | catalogued as COSV73310596; called by muse, mutect2, varscan2
- TTN | c.50418G>A p.P16806= (on ENST00000591111; = p.P9382= on NM_003319.4) | Silent (SNP) | VAF 83/324 reads (26%) | catalogued as rs779464399, COSV59885490; called by muse, mutect2, varscan2
